Somatic mutation profile of tumor specimen TCGA-55-A4DG-01A (aliquot TCGA-55-A4DG-01A-11D-A24D-08) from TCGA case TCGA-55-A4DG, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.3 years (26,044 days).
Specimen TCGA-55-A4DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64749795-d448-4308-b810-0db71295f28c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A4DG-10A (Blood Derived Normal), aliquot TCGA-55-A4DG-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c551e781-f69d-4cd8-b85f-41e6f50e7ebe

The open-access MAF lists 750 somatic variants for this specimen: 576 protein-altering or splice-affecting, 149 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 494, Silent 149, Nonsense Mutation 45, Frame Shift Del 20, Intron 12, Splice Site 10, RNA 8, Frame Shift Ins 3, Translation Start Site 2, 3'UTR 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs869312700, COSV100487133; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4930G>T p.D1644Y (on ENST00000358273 / NM_001042492.3; = p.D1623Y on NM_000267.3) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691123, CM143422, CM143423, CM1512957, COSV55986770, COSV99907744; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 50/94 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2034+1G>T p.X678_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100972887; called by muse, mutect2, varscan2
- ABCC8 | c.3998T>C p.L1333P | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100217836; called by muse, mutect2, varscan2
- AC006059.2 | c.1232T>C p.M411T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs767266612, COSV100046075; called by muse, mutect2, varscan2
- AC008676.3 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100400541; called by muse, mutect2, varscan2
- ACADL | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs370145222; called by muse, mutect2, varscan2
- ACAP2 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100462915; called by muse, mutect2, varscan2
- ACTL9 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as COSV100185595; called by muse, mutect2
- ACTN3 | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100074211, COSV59750529; called by muse, mutect2, varscan2
- ADAM30 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101024009; called by muse, mutect2
- ADAM33 | c.1553C>A p.A518E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as rs774280799, COSV100598122; called by muse, mutect2, varscan2
- ADAMTS2 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99206298; called by muse, mutect2, varscan2
- ADAMTS20 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1251606118; called by muse, mutect2, varscan2
- ADCY2 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs754895065, COSV100604552; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417042; called by muse, mutect2, varscan2
- ADGRF1 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.759); catalogued as COSV100982707; called by muse, mutect2, varscan2
- ADGRG4 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99797356; called by muse, mutect2, varscan2
- ADGRL2 | c.2794G>T p.G932C (on ENST00000370717 / NM_001366005.1; = p.G919C on NM_012302.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs900691021, COSV99591995; called by muse, mutect2, varscan2
- ADGRL3 | c.3605A>T p.Y1202F (on ENST00000506720 / NM_001322402.2; = p.Y1134F on NM_015236.6) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV101547439; called by muse, mutect2
- ADGRL3 | c.3607G>A p.G1203R (on ENST00000506720 / NM_001322402.2; = p.G1135R on NM_015236.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.944); catalogued as COSV72231572; called by muse, mutect2
- ADGRV1 | c.9214G>T p.G3072C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs757560169, COSV101316666; called by muse, mutect2
- ADRA2B | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs773495006, COSV101337398, COSV69787824; called by muse, mutect2, varscan2
- AGBL1 | c.2294C>A p.T765K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101224391, COSV66858368; called by muse, mutect2, varscan2
- ALDOB | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as rs759273480, COSV100878949; called by muse, mutect2, varscan2
- ALPK1 | c.1996C>G p.Q666E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99455362; called by muse, mutect2, varscan2
- AMER3 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.211); catalogued as COSV58471446; called by muse, mutect2, varscan2
- AMPD1 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100815331, COSV62418337; called by muse, mutect2, varscan2
- AMZ1 | c.291C>A p.Y97* | Nonsense Mutation (SNP) | VAF 54/119 reads (45%) | catalogued as COSV100406650; called by muse, mutect2, varscan2
- ANAPC1 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100595164; called by muse, varscan2
- ANAPC7 | c.1200A>G p.I400M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV101482883; called by muse, mutect2, varscan2
- ANK2 | c.5246C>T p.P1749L | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.164); catalogued as COSV100004702; called by muse, mutect2, varscan2
- ANK3 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV99782921; called by muse, mutect2, varscan2
- ANKMY1 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs772827899, COSV99803536; called by mutect2, varscan2
- AOC1 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711050; called by muse, mutect2, varscan2
- AOC3 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99520487; called by muse, mutect2, varscan2
- APCDD1L | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100954120; called by muse, mutect2, varscan2
- ARMC3 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 23/30 reads (77%) | catalogued as COSV99959067; called by muse, mutect2, varscan2
- ARNTL2 | c.1666-1G>T p.X556_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99668167; called by muse, mutect2, varscan2
- ASB5 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1331735767, COSV99642218; called by muse, mutect2, varscan2
- ATP13A3 | c.3644C>T p.A1215V (on ENST00000645319 / NM_001367549.1; = p.A1185V on NM_024524.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99757766; called by muse, mutect2, varscan2
- ATP13A4 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100710828; called by muse, mutect2, varscan2
- ATP2B1 | c.3114A>G p.I1038M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs758857340, COSV99666295; called by muse, mutect2, varscan2
- ATP2B2 | c.1192G>T p.V398L (on ENST00000352432; = p.V364L on NM_001683.5) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100659448, COSV100660600; called by muse, mutect2, varscan2
- ATP7B | c.3557G>T p.G1186V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766800003, COSV99667045; called by muse, mutect2
- ATP8A2 | c.1473+1G>T p.X491_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99684876; called by muse, mutect2
- ATP8B2 | c.1446G>T p.W482C (on ENST00000672630; = p.W449C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.263); catalogued as COSV100528311, COSV59246450; called by muse, mutect2
- B3GAT2 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV57769086; called by muse, mutect2, varscan2
- B3GNT6 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100845819, COSV62828321, COSV62828333; called by muse, mutect2, varscan2
- B4GALNT1 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100247361, COSV57544855; called by muse, mutect2, varscan2
- BAIAP3 | c.2781G>T p.Q927H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99136426; called by muse, mutect2, varscan2
- BARHL1 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99707758; called by muse, mutect2, varscan2
- BCAN | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228569; called by muse, mutect2, varscan2
- BCL11A | c.584G>T p.G195V (on ENST00000335712 / NM_001365609.1; = p.G229V on NM_018014.4) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV100186729; called by muse, mutect2, varscan2
- BDP1 | c.6976G>C p.E2326Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV100703662, COSV62430642; called by muse, mutect2, varscan2
- BICDL1 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV101287564; called by muse, mutect2, varscan2
- BMP10 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99770672; called by muse, mutect2, varscan2
- BPIFC | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100301321; called by muse, mutect2
- BSN | c.7667G>C p.R2556P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs767629394, COSV56518832, COSV99610116; called by muse, mutect2, varscan2
- C10orf71 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100110749; called by muse, mutect2, varscan2
- CA10 | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99565727; called by muse, mutect2, varscan2
- CACNA1C | c.3751A>G p.M1251V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV100223345; called by muse, mutect2, varscan2
- CACNA1E | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100701272; called by muse, mutect2
- CACNA1E | c.4769G>C p.G1590A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100705792; called by muse, mutect2, varscan2
- CACNA2D1 | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62381979; called by muse, mutect2, varscan2
- CACNG7 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55816756; called by muse, mutect2, varscan2
- CAD | c.5290A>T p.M1764L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99256022; called by mutect2, varscan2
- CAMP | c.409C>A p.L137M (on ENST00000296435; = p.L134M on NM_004345.5) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.179); catalogued as COSV99601341; called by muse, mutect2, varscan2
- CAPSL | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV101274354; called by muse, mutect2
- CARMIL1 | c.1841A>C p.Q614P | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100278998; called by muse, mutect2, varscan2
- CBWD1 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV100071357; called by muse, mutect2, varscan2
- CCDC138 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99718935, COSV99719620; called by muse, mutect2, varscan2
- CCDC14 | c.833A>T p.D278V (on ENST00000488653; = p.D230V on NM_022757.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV100113502; called by muse, mutect2, varscan2
- CCDC39 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV56481305, COSV99870925; called by muse, mutect2, varscan2
- CCHCR1 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 96/173 reads (55%) | catalogued as COSV100885926; called by muse, mutect2, varscan2
- CCN3 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52383844; called by muse, mutect2
- CCN4 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs1034154929, COSV99137563; called by muse, mutect2, varscan2
- CD1A | c.38del p.P13Qfs*37 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as COSV56863678; called by mutect2, pindel, varscan2
- CD1A | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV99192658; called by muse, mutect2
- CDH10 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100053466, COSV52600363; called by muse, mutect2, varscan2
- CDH6 | c.966G>C p.Q322H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV99420239, COSV99421176; called by muse, mutect2
- CDH8 | c.1556C>A p.A519D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100184569; called by muse, mutect2, varscan2
- CDH9 | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99162829; called by muse, mutect2, varscan2
- CEACAM8 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV54992290, COSV99747918; called by muse, mutect2, varscan2
- CELA3B | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs368231510, COSV100448895; called by muse, mutect2, varscan2
- CFAP221 | c.1780A>C p.K594Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99733324; called by muse, mutect2, varscan2
- CFAP47 | c.2507G>C p.G836A | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99935987; called by muse, mutect2, varscan2
- CFAP74 | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54572196; called by muse, mutect2, varscan2
- CFAP94 | c.520G>T p.E174* (on ENST00000320267 / NM_001352064.2; = p.E180* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99060669; called by muse, mutect2, varscan2
- CFC1 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52090959, COSV99383541; called by muse, mutect2, varscan2
- CHAT | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV60326044; called by muse, mutect2, varscan2
- CHST1 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1286733851, COSV100346583; called by muse, mutect2, varscan2
- CHUK | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100957301; called by muse, mutect2
- CLCN2 | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV99659104; called by muse, mutect2, varscan2
- CLCN4 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV66466209; called by muse, mutect2, varscan2
- CLCN6 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs149322151; called by muse, mutect2, varscan2
- CLPX | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100269713; called by muse, mutect2, varscan2
- CMA1 | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99157825; called by muse, mutect2, varscan2
- CNTN2 | c.2413G>T p.V805L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100085604; called by muse, mutect2, varscan2
- COL11A1 | c.3385G>T p.G1129C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618320; called by muse, mutect2, varscan2
- COL14A1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as rs767026354, COSV99920968; called by muse, mutect2, varscan2
- COL19A1 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100507741; called by muse, mutect2, varscan2
- COL1A1 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56803713; called by muse, mutect2, varscan2
- COL3A1 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100483903; called by muse, mutect2, varscan2
- COL4A4 | c.2311G>T p.G771* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100307966, COSV61633828; called by muse, mutect2, varscan2
- COL5A2 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100880944; called by muse, mutect2, varscan2
- COP1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV100444063; called by muse, mutect2, varscan2
- CPAMD8 | c.2302C>T p.Q768* (on ENST00000651564; = p.Q721* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99359913; called by muse, mutect2, varscan2
- CPNE8 | c.1164_1165insG p.Y389Vfs*3 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | catalogued as COSV100505231; called by mutect2, pindel, varscan2
- CPZ | c.966C>A p.N322K (on ENST00000360986 / NM_001014447.3; = p.N311K on NM_003652.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100249353; called by muse, mutect2, varscan2
- CRACD | c.2404A>T p.S802C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99950173; called by muse, mutect2, varscan2
- CRB2 | c.2593G>T p.G865C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63505218; called by muse, mutect2, varscan2
- CREB1 | c.602T>A p.V201E (on ENST00000432329 / NM_134442.5; = p.V187E on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100783654; called by muse, mutect2, varscan2
- CRX | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55758508, COSV55760600; called by muse, mutect2, varscan2
- CSMD2 | c.4241G>A p.G1414D | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99596714; called by muse, mutect2, varscan2
- CSMD3 | c.2857G>A p.D953N (on ENST00000297405 / NM_001363185.1; = p.D849N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52297606, COSV99851150; called by muse, mutect2, varscan2
- CST8 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as COSV99850126; called by muse, mutect2, varscan2
- CTDSPL2 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52947917; called by muse, mutect2
- CTRC | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV101036487; called by muse, mutect2, varscan2
- CUX2 | c.2449G>T p.G817C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV99921026; called by muse, mutect2, varscan2
- CYP2C9 | c.756A>T p.Q252H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV99583344; called by muse, mutect2, varscan2
- DAPL1 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775660380, COSV100007442; called by muse, mutect2, varscan2
- DBX1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99910365; called by muse, mutect2
- DCAF12L1 | c.1083C>A p.H361Q | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100948481, COSV64422940; called by muse, mutect2, varscan2
- DIPK2A | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.644); catalogued as COSV100237524; called by muse, mutect2, varscan2
- DIRAS2 | c.340A>T p.I114F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV101005928; called by muse, mutect2, varscan2
- DLK1 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375516; called by muse, mutect2, varscan2
- DNAH2 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV50021238; called by muse, mutect2, varscan2
- DNAH5 | c.3577G>T p.G1193C | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99448710; called by muse, mutect2
- DNAH5 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99455372; called by muse, mutect2, varscan2
- DOCK2 | c.3295C>A p.P1099T | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99916175; called by muse, mutect2, varscan2
- DOP1B | c.2291del p.P764Lfs*31 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | catalogued as COSV67694046; called by mutect2, pindel, varscan2
- DPY19L3 | c.1434G>C p.L478F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100639313, COSV100639338; called by muse, mutect2, varscan2
- DSG1 | c.2372C>A p.P791H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99936698; called by muse, mutect2, varscan2
- EBF3 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100799712; called by muse, mutect2, varscan2
- EEPD1 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.781); catalogued as COSV99633269; called by muse, mutect2, varscan2
- EIF2AK3 | c.1974G>T p.W658C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57545597; called by muse, mutect2, varscan2
- EIF5B | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99179024; called by muse, mutect2, varscan2
- ENO1 | c.1276A>T p.R426W | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV99319042; called by muse, mutect2, varscan2
- ENOSF1 | c.514G>C p.D172H (on ENST00000340116 / NM_001354066.2; = p.D124H on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99201208; called by muse, mutect2, varscan2
- EPHA2 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100626353; called by muse, mutect2, varscan2
- EPM2AIP1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV51624375, COSV99212860; called by muse, mutect2, varscan2
- EPM2AIP1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99212861; called by muse, mutect2, varscan2
- ESR1 | c.1157T>A p.I386N | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99241759; called by muse, mutect2, varscan2
- ETNK1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99861073; called by muse, mutect2
- EXOC8 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99150186; called by muse, mutect2, varscan2
- F2 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100319748; called by muse, mutect2, varscan2
- F5 | c.5676G>T p.Q1892H | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100889288; called by muse, mutect2, varscan2
- FAM120AOS | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV99466810; called by muse, mutect2
- FAM153B | c.730G>T p.V244L (on ENST00000253490; = p.V167L on NM_001265615.1) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.22); catalogued as COSV99499200; called by muse, mutect2
- FAM83B | c.2945A>T p.N982I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV100175179; called by muse, mutect2, varscan2
- FANCD2 | c.3476C>T p.A1159V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99812803; called by muse, mutect2, varscan2
- FAT3 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53084939, COSV99972235; called by muse, mutect2, varscan2
- FBXO46 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs780524627, COSV100480485; called by muse, mutect2, varscan2
- FGFR1 | c.1343G>T p.R448L (on ENST00000447712 / NM_023110.3; = p.R446L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs758138124, COSV58338600, COSV58340503; called by muse, mutect2, varscan2
- FIBCD1 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99447613; called by muse, mutect2, varscan2
- FIP1L1 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1038763614, COSV100184881; called by muse, mutect2, varscan2
- FLG2 | c.3955G>A p.G1319R | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV66166773; called by muse, mutect2, varscan2
- FLII | c.2555C>G p.A852G | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100375758, COSV100375823; called by muse, mutect2, varscan2
- FLT1 | c.2078C>A p.T693N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV99169646; called by muse, mutect2, varscan2
- FLYWCH1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV99559389; called by muse, mutect2, varscan2
- FOXO3 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100670283; called by muse, mutect2, varscan2
- FREM1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 2/18 reads (11%) | catalogued as COSV66521711; called by muse, mutect2
- FRMPD4 | c.3216C>A p.D1072E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.048); catalogued as COSV101044284; called by muse, mutect2, varscan2
- FRMPD4 | c.3217A>C p.S1073R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); catalogued as COSV101044285; called by muse, mutect2, varscan2
- FRY | c.7991T>C p.F2664S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as COSV100970031; called by muse, mutect2, varscan2
- FZD8 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.228); catalogued as COSV101020280; called by muse, mutect2, varscan2
- GALNT15 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100327277; called by muse, mutect2, varscan2
- GBP6 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs181179151, COSV100969724; called by muse, mutect2, varscan2
- GCG | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 22/183 reads (12%) | catalogued as COSV100972880; called by muse, mutect2, varscan2
- GCSAML | c.9T>A p.N3K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100826059; called by muse, mutect2, varscan2
- GFRA3 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99218584; called by muse, mutect2, varscan2
- GGTLC1 | c.86T>C p.F29S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99601018; called by muse, mutect2, varscan2
- GLI3 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV101230142; called by muse, mutect2, varscan2
- GNB4 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99224609; called by muse, mutect2
- GPR12 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV101198036; called by muse, mutect2, varscan2
- GPR39 | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100258787, COSV100258811; called by muse, mutect2, varscan2
- GPR87 | c.568C>A p.H190N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53462106, COSV99608979; called by muse, mutect2, varscan2
- GRID1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.138); catalogued as COSV100027063; called by muse, mutect2, varscan2
- GRM7 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63144893, COSV63157411; called by muse, mutect2, varscan2
- GTF3C2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV99273394; called by muse, mutect2, varscan2
- GUCY1A2 | c.2117C>A p.P706Q | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV99977494; called by muse, mutect2, varscan2
- H4C2 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs752050927, COSV99775186, COSV99775221; called by muse, mutect2, varscan2
- HAPLN3 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613901; called by muse, mutect2, varscan2
- HCN1 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV100302693, COSV57525389; called by muse, mutect2, varscan2
- HERC2 | c.1756+1G>A p.X586_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99877506; called by muse, mutect2
- HIVEP1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192064941, COSV65105388; called by muse, mutect2, varscan2
- HJV | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100382436; called by muse, mutect2, varscan2
- HOMEZ | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100664219; called by muse, mutect2, varscan2
- HOXD13 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV101184368; called by muse, mutect2, varscan2
- HRNR | c.8509C>T p.P2837S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.103); catalogued as COSV100914035; called by muse, mutect2
- HTR1A | c.1006G>C p.A336P | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV100109322; called by muse, mutect2, varscan2
- HTR1A | c.839C>A p.A280E | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV100109324, COSV60500024; called by muse, mutect2, varscan2
- HTR3B | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs138942341, COSV99492400; called by muse, mutect2, varscan2
- IARS2 | c.2044G>T p.G682* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100228692; called by muse, mutect2, varscan2
- IARS2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228693; called by muse, mutect2, varscan2
- ICE1 | c.1788A>T p.K596N | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV99665991; called by muse, mutect2, varscan2
- ICE1 | c.2704G>T p.A902S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV99665994; called by muse, mutect2
- ICE1 | c.5197C>G p.P1733A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99665999; called by muse, mutect2
- IFI27L1 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67628582; called by muse, mutect2, varscan2
- IFNA16 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV101207094; called by muse, mutect2
- IFNA17 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101303489; called by muse, mutect2, varscan2
- IGHV3-72 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | catalogued as rs368822919; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs556657808; called by muse, mutect2, varscan2
- IGLV2-18 | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs1370424060; called by muse, mutect2, varscan2
- IL18RAP | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99962512; called by muse, mutect2, varscan2
- IL4R | c.1309G>T p.G437* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99405469; called by muse, mutect2, varscan2
- INPP4B | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99527288; called by muse, mutect2, varscan2
- INTS6L | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100878353, COSV66084091, COSV66086619; called by muse, mutect2, varscan2
- IRF4 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101110978, COSV66704934; called by muse, mutect2, varscan2
- IRF8 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV99236947; called by muse, mutect2, varscan2
- ITGA4 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276945; called by muse, varscan2
- ITK | c.191A>C p.E64A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101439909; called by muse, mutect2, varscan2
- ITK | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV101439910; called by muse, mutect2, varscan2
- JAKMIP2 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99509449; called by muse, mutect2, varscan2
- JHY | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99913911; called by muse, mutect2, varscan2
- KAT2B | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99770008; called by muse, varscan2
- KAT2B | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.437); catalogued as COSV99770010; called by muse, varscan2
- KCNA6 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as rs372964376, COSV99769076; called by muse, mutect2, varscan2
- KCNH5 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100528478, COSV59768272; called by muse, mutect2, varscan2
- KCNJ8 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs764730358, COSV53716062; called by muse, mutect2, varscan2
- KIAA0319L | c.1103A>T p.K368I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs1183128585, COSV100357810; called by muse, mutect2, varscan2
- KIAA1614 | c.334T>G p.S112A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV100851373; called by muse, mutect2, varscan2
- KIF19 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as COSV100739211; called by muse, mutect2, varscan2
- KIF1B | c.1691A>T p.E564V (on ENST00000377086 / NM_001365952.1; = p.E518V on NM_015074.3) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV99824407; called by muse, mutect2, varscan2
- KIF21B | c.3883A>T p.T1295S (on ENST00000422435 / NM_001252100.2; = p.T1282S on NM_017596.4) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.97); catalogued as COSV100145273; called by muse, mutect2, varscan2
- KIZ | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99852483; called by muse, mutect2, varscan2
- KLF17 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1162275301, COSV64856724; called by muse, mutect2, varscan2
- KLF17 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV100955050; called by muse, mutect2, varscan2
- KLHL32 | c.1577G>C p.W526S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987526; called by muse, mutect2, varscan2
- KLHL5 | c.1715G>T p.W572L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99786083; called by muse, mutect2, varscan2
- KRT82 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV99233946; called by muse, mutect2, varscan2
- KRTAP21-2 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61684262, COSV61684736; called by muse, mutect2, varscan2
- KRTAP6-1 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | PolyPhen probably damaging (1); catalogued as COSV100228862; called by muse, varscan2
- LAMP1 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV100208821; called by muse, mutect2, varscan2
- LCE4A | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100140119; called by muse, mutect2
- LHCGR | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99684347; called by muse, mutect2, varscan2
- LILRA2 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV99254083; called by muse, mutect2, varscan2
- LILRA5 | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100007161; called by muse, mutect2, varscan2
- LILRB1 | c.409G>C p.G137R (on ENST00000427581; = p.G101R on NM_006669.6) | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as COSV100208031; called by muse, mutect2
- LRP12 | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52632842; called by muse, mutect2, varscan2
- LRP1B | c.11438G>T p.G3813V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101262137; called by muse, mutect2, varscan2
- LRP1B | c.6265G>T p.V2089F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV101262138; called by muse, mutect2
- LRP1B | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV101262139; called by muse, mutect2, varscan2
- LRP2 | c.9173G>T p.G3058V | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99790679; called by muse, mutect2
- LRP2 | c.9171T>G p.C3057W | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790681; called by muse, mutect2
- LRRC7 | c.2653A>T p.R885* (on ENST00000651989 / NM_001370785.2; = p.R852* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as COSV99230475; called by muse, mutect2, varscan2
- LRRC7 | c.3704G>T p.R1235M (on ENST00000651989 / NM_001370785.2; = p.R1202M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50413693, COSV99230483; called by muse, varscan2
- LRRTM4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101297759; called by mutect2, varscan2
- LTK | c.1184T>A p.L395H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV99541221; called by muse, mutect2, varscan2
- LY75 | c.2279G>T p.R760M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99717168; called by muse, mutect2
- LYG2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV100283830; called by muse, mutect2, varscan2
- MAB21L1 | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100084997; called by muse, mutect2, varscan2
- MAB21L2 | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100462473; called by muse, mutect2, varscan2
- MACROH2A2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325844; called by muse, mutect2, varscan2
- MAGEL2 | c.3014C>A p.A1005D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV100046322; called by muse, mutect2, varscan2
- MAP1LC3C | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.012); catalogued as COSV100606581; called by muse, mutect2
- MAP2 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as rs754498427, COSV99562057; called by muse, mutect2, varscan2
- MAP2 | c.3647A>T p.D1216V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.898); catalogued as rs932744669, COSV99562058; called by muse, mutect2, varscan2
- MAPT | c.1703C>A p.P568Q (on ENST00000262410 / NM_001377265.1; = p.P176Q on NM_005910.5) | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52237979, COSV99291530; called by muse, mutect2, varscan2
- MARF1 | c.4355G>T p.C1452F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100706491; called by muse, mutect2, varscan2
- MAT1A | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100944502; called by muse, mutect2, varscan2
- MATN2 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647327; called by muse, mutect2
- MBTPS1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs773118504, COSV58572110; called by muse, mutect2, varscan2
- MCHR1 | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV99967923; called by muse, mutect2
- MEP1B | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV99329217; called by muse, mutect2, varscan2
- METTL22 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs745452183, COSV99371572; called by muse, mutect2, varscan2
- MIA2 | c.277A>T p.R93* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99696973; called by muse, mutect2, varscan2
- MIOX | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99327161; called by muse, mutect2, varscan2
- MMP16 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99685668, COSV99690847; called by muse, mutect2, varscan2
- MOS | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972725148, COSV100323059; called by muse, mutect2
- MPP4 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207479; called by muse, mutect2, varscan2
- MPPED2 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100813578; called by muse, mutect2, varscan2
- MSH4 | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99592795; called by mutect2, varscan2
- MSI2 | c.652+1G>T p.X218_splice | Splice Site (SNP) | VAF 50/113 reads (44%) | catalogued as COSV99403755; called by muse, mutect2, varscan2
- MTNR1B | c.946C>A p.R316S | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99925412; called by muse, mutect2, varscan2
- MUC16 | c.40208G>T p.S13403I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.974); catalogued as rs1362625682, COSV66689601; called by muse, mutect2, varscan2
- MUC16 | c.14290C>A p.P4764T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101202112; called by muse, mutect2, varscan2
- MUC16 | c.2948C>T p.T983I | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV101202113; called by muse, mutect2, varscan2
- MUC17 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV100075510; called by muse, mutect2, varscan2
- MUC17 | c.4768G>A p.A1590T | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100075513, COSV60307246; called by muse, mutect2, varscan2
- MUC17 | c.11793A>T p.E3931D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV60303398; called by muse, mutect2, varscan2
- MUC7 | c.679T>G p.S227A | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100512412, COSV59217054; called by muse, varscan2
- MYBPC1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100638330; called by muse, mutect2, varscan2
- MYH1 | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs543784627, COSV99877158; called by muse, mutect2, varscan2
- MYH7 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100806823, COSV62517939; called by muse, mutect2, varscan2
- MYLK2 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV101044980; called by muse, mutect2, varscan2
- MYO18B | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100125550; called by muse, mutect2, varscan2
- NALCN | c.4364C>A p.S1455Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51915119, COSV51937478; called by muse, mutect2
- NAV3 | c.2839C>A p.P947T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs781411104, COSV57072380; called by muse, varscan2
- NCAM2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV99525875; called by muse, mutect2, varscan2
- NFKBIB | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as rs1292210423, COSV100548563; called by muse, mutect2, varscan2
- NINL | c.3007G>T p.G1003C | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as COSV99626589; called by muse, mutect2, varscan2
- NLGN1 | c.2224C>A p.H742N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.253); catalogued as COSV100850373, COSV64339098; called by muse, mutect2, varscan2
- NLRC3 | c.3140C>A p.A1047D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100073601; called by muse, mutect2, varscan2
- NLRP12 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317584720, COSV100144865, COSV100146050; called by muse, mutect2, varscan2
- NLRP13 | c.3104C>A p.S1035* | Nonsense Mutation (SNP) | VAF 46/146 reads (32%) | catalogued as COSV100738637, COSV61621599; called by muse, mutect2, varscan2
- NOX4 | c.1135+2T>A p.X379_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99632272; called by muse, mutect2, varscan2
- NPAP1 | c.3331G>T p.V1111F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as COSV100276357; called by muse, mutect2, varscan2
- NPR3 | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99424013; called by muse, mutect2, varscan2
- NRDC | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs778552393, COSV100703987; called by muse, mutect2, varscan2
- NRDE2 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583703, COSV62964136; called by muse, mutect2, varscan2
- NSUN3 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100113516; called by muse, mutect2, varscan2
- NTNG1 | c.999T>A p.Y333* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99640062; called by muse, mutect2, varscan2
- NUP155 | c.3589A>G p.K1197E (on ENST00000231498 / NM_153485.3; = p.K1138E on NM_004298.4) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV99195530; called by muse, mutect2, varscan2
- NXPH1 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV101339835; called by muse, mutect2, varscan2
- OAS1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99177338; called by muse, mutect2, varscan2
- OBSCN | c.14900G>C p.G4967A | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52750511, COSV99485715; called by muse, mutect2
- OPN5 | c.213G>T p.M71I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV99790100; called by muse, mutect2, varscan2
- OR10X1 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100936629, COSV100936723; called by muse, mutect2, varscan2
- OR14A16 | c.722C>A p.P241Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100713891; called by muse, mutect2, varscan2
- OR1S2 | c.232T>A p.Y78N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372935853; called by muse, mutect2, varscan2
- OR2B11 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100276800, COSV59510350; called by muse, mutect2, varscan2
- OR2D3 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100505179; called by muse, mutect2, varscan2
- OR2D3 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100505180, COSV58572942; called by muse, mutect2, varscan2
- OR2K2 | c.472C>A p.P158T (on ENST00000374428; = p.P129T on NM_205859.2) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57018164, COSV57018219; called by muse, mutect2, varscan2
- OR2L3 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV100742079; called by muse, mutect2, varscan2
- OR2T11 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100424998; called by muse, mutect2
- OR2W3 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV100831882; called by muse, mutect2, varscan2
- OR3A2 | c.686A>T p.H229L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV101375093; called by muse, mutect2, varscan2
- OR4K13 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV100237932, COSV59858903; called by muse, mutect2, varscan2
- OR4M1 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100271572, COSV60061978; called by muse, mutect2
- OR4Q3 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100057492; called by muse, mutect2, varscan2
- OR51A7 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1345656284, COSV100834778; called by muse, mutect2, varscan2
- OR51B5 | c.767T>G p.L256W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100332722; called by muse, mutect2, varscan2
- OR52H1 | c.876G>T p.M292I (on ENST00000322653; = p.M298I on NM_001005289.1) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100497391; called by muse, mutect2, varscan2
- OR52K2 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs925205988, COSV100355895; called by muse, mutect2, varscan2
- OR5A1 | c.737C>A p.S246* | Nonsense Mutation (SNP) | VAF 49/162 reads (30%) | catalogued as COSV100118497, COSV57376428; called by muse, mutect2, varscan2
- OR5AR1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as COSV100265624, COSV100265857; called by muse, mutect2, varscan2
- OR5M1 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs767654423, COSV101591622; called by muse, mutect2, varscan2
- OR6K2 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100656920, COSV62743615; called by muse, mutect2, varscan2
- OR6T1 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100190237, COSV100190292; called by muse, mutect2
- OSBPL6 | c.2369T>A p.V790E | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99508830; called by muse, mutect2, varscan2
- OTOF | c.2450A>T p.K817M (on ENST00000272371 / NM_194248.3; = p.K70M on NM_004802.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV99719298; called by muse, mutect2, varscan2
- OTOGL | c.4528C>A p.P1510T (on ENST00000547103; = p.P1501T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV100086863, COSV100088059; called by muse, mutect2, varscan2
- PADI2 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100971117; called by muse, mutect2, varscan2
- PADI6 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100640048; called by muse, mutect2, varscan2
- PALD1 | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99698413, COSV99698784; called by muse, mutect2
- PAPPA | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100075668; called by muse, mutect2, varscan2
- PAPPA | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765997320, COSV100074380, COSV100075671; called by muse, mutect2, varscan2
- PAPPA2 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473020459, COSV100867258; called by muse, mutect2, varscan2
- PCDH10 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.65); catalogued as rs754653138, COSV52096329, COSV52102015; called by muse, mutect2, varscan2
- PCDH15 | c.4444G>A p.V1482M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV100227835, COSV100229083; called by muse, mutect2, varscan2
- PCDH17 | c.3398T>A p.V1133E | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV100932171; called by muse, mutect2, varscan2
- PCDHA2 | c.1534G>C p.A512P | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV100974185, COSV65369133; called by muse, varscan2
- PCDHA9 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100970206; called by muse, mutect2, varscan2
- PCDHB13 | c.2318A>T p.N773I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99507987; called by muse, mutect2, varscan2
- PCDHGA3 | c.1940A>G p.Q647R | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV99549014; called by muse, mutect2, varscan2
- PCDHGA4 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99549016; called by muse, mutect2, varscan2
- PCDHGA6 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as COSV99549018; called by muse, mutect2, varscan2
- PDCD10 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101208545; called by mutect2, varscan2
- PDE6A | c.509C>G p.T170R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678811; called by muse, mutect2, varscan2
- PDZD3 | c.1285G>T p.E429* (on ENST00000531114; = p.E349* on NM_024791.4) | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV99425032; called by muse, mutect2, varscan2
- PDZRN3 | c.2628C>A p.H876Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99732748; called by muse, mutect2, varscan2
- PGBD5 | c.789C>A p.N263K (on ENST00000525115; = p.N332K on NM_001258311.2) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV100358965; called by muse, mutect2, varscan2
- PGK2 | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100505746; called by muse, mutect2, varscan2
- PHF14 | c.1678del p.V560Ffs*61 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV68857632; called by mutect2, pindel, varscan2
- PIK3AP1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100226322; called by muse, mutect2, varscan2
- PKD1L1 | c.7043G>A p.G2348D | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99221717; called by muse, mutect2, varscan2
- PKNOX1 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99373193; called by muse, mutect2, varscan2
- PKP2 | c.748C>G p.R250G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV99298614; called by muse, mutect2, varscan2
- PLAAT4 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99737906; called by muse, mutect2, varscan2
- PLAT | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 48/179 reads (27%) | catalogued as COSV54277646, COSV54277658, COSV99535497; called by muse, mutect2, varscan2
- PLCB4 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53791464, COSV99597223; called by muse, mutect2, varscan2
- PLEK | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV99311301; called by muse, mutect2, varscan2
- PLVAP | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.448); catalogued as rs772418879, COSV53086645; called by muse, mutect2, varscan2
- PMFBP1 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99401690; called by muse, mutect2, varscan2
- PML | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.754); catalogued as rs1438297871, COSV51441538; called by muse, mutect2, varscan2
- POLM | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99642033; called by muse, mutect2, varscan2
- POSTN | c.2166A>T p.E722D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV101123536; called by muse, mutect2, varscan2
- POTEH | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100625302, COSV58881926; called by muse, mutect2
- PPP4R4 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs1333366115, COSV100429117; called by muse, mutect2
- PRAMEF2 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99535820; called by muse, mutect2, varscan2
- PRKCH | c.1006A>T p.S336C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV100273879, COSV60649682; called by muse, mutect2, varscan2
- PROKR2 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as COSV99450743; called by muse, mutect2, varscan2
- PRPF40B | c.2501G>A p.G834D (on ENST00000380281; = p.G821D on NM_012272.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); catalogued as COSV99527213; called by muse, mutect2, varscan2
- PRR23B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.583); catalogued as COSV61494052; called by muse, mutect2, varscan2
- PRRC2C | c.440G>T p.S147I (on ENST00000367742; = p.S145I on NM_015172.4) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100146277; called by muse, mutect2
- PRUNE2 | c.4237C>G p.R1413G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100945281, COSV65040724; called by muse, mutect2, varscan2
- PSG2 | c.644A>C p.Y215S | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753536629, COSV61547056; called by muse, mutect2, varscan2
- PSMC2 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99485484; called by muse, mutect2, varscan2
- PSMC6 | c.1135G>T p.E379* (on ENST00000612399; = p.E365* on NM_002806.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100648351; called by muse, mutect2, varscan2
- PTCHD3 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs766604262, COSV101438980; called by muse, mutect2
- PTTG2 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.99); catalogued as COSV99792423; called by muse, mutect2, varscan2
- PYDC2 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376347470, COSV101573374; called by muse, mutect2, varscan2
- R3HDML | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.339); catalogued as COSV99407326; called by muse, mutect2
- RANBP3L | c.268+2T>A p.X90_splice | Splice Site (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99684131; called by muse, mutect2
- RASL10A | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99329757; called by muse, mutect2, varscan2
- RAX2 | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765285304, COSV100349801; called by muse, varscan2
- RBFOX2 | c.1085C>T p.P362L (on ENST00000438146 / NM_001349995.2; = p.P288L on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99455915; called by muse, mutect2, varscan2
- RBM41 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99179776; called by muse, mutect2, varscan2
- RCBTB2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1320636681, COSV100749667, COSV60649259; called by muse, mutect2
- RCBTB2 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100749668; called by muse, mutect2
- RDH8 | c.349G>T p.G117W (on ENST00000651512; = p.G97W on NM_015725.4) | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408836; called by muse, mutect2
- RELL2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99781579; called by muse, mutect2, varscan2
- REM1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52428007, COSV99148120; called by muse, mutect2, varscan2
- REST | c.2965G>C p.A989P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV100471426; called by muse, mutect2, varscan2
- RGS7BP | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100471470; called by muse, mutect2
- RING1 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100761886; called by muse, mutect2, varscan2
- RP1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1436761719, COSV55110274; called by muse, mutect2, varscan2
- RPRD2 | c.4121A>T p.H1374L | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100955437; called by muse, mutect2, varscan2
- RPS4Y2 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV99978448; called by muse, mutect2, varscan2
- RPS6KC1 | c.2710G>T p.G904C | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100874133; called by muse, mutect2, varscan2
- RUSC2 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100770943; called by muse, mutect2, varscan2
- RYR1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100617279; called by muse, mutect2, varscan2
- RYR2 | c.7586C>A p.T2529K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100773268; called by muse, mutect2, varscan2
- S100A7 | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV100906766; called by muse, mutect2, varscan2
- SALL3 | c.1900C>A p.P634T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV101610080; called by muse, mutect2, varscan2
- SALL3 | c.2994C>G p.S998R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101610065, COSV101610081; called by muse, mutect2, varscan2
- SAMD9L | c.2057A>C p.H686P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV100561216; called by muse, mutect2, varscan2
- SAMHD1 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV99484383; called by muse, mutect2, varscan2
- SASH1 | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821528; called by muse, mutect2, varscan2
- SCN10A | c.5210G>A p.S1737N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV101479575; called by muse, mutect2, varscan2
- SCN4A | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV101438708; called by muse, mutect2, varscan2
- SCUBE1 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100683873, COSV62611447; called by muse, mutect2, varscan2
- SEC23IP | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100957151; called by muse, mutect2, varscan2
- SERGEF | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99787974; called by muse, mutect2, varscan2
- SFPQ | c.1921G>T p.G641C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599533, COSV61759210; called by muse, mutect2, varscan2
- SFPQ | c.1805A>T p.Y602F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV100599534; called by muse, mutect2, varscan2
- SHANK1 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV53256843, COSV99522250; called by mutect2, varscan2
- SHOX | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61860481; called by muse, varscan2
- SHOX | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 27/209 reads (13%) | catalogued as COSV100479339; called by muse, varscan2
- SI | c.3613G>C p.A1205P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV100017517, COSV52271939; called by muse, mutect2, varscan2
- SI | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100017518, COSV104387843; called by muse, mutect2, varscan2
- SIGLEC10 | c.1402G>C p.A468P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100219507; called by muse, mutect2, varscan2
- SIRPG | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV99404063; called by muse, mutect2, varscan2
- SLAMF7 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100833389; called by muse, mutect2, varscan2
- SLC17A8 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773113592, COSV100035941; called by muse, mutect2, varscan2
- SLC22A16 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100398029; called by muse, mutect2, varscan2
- SLC22A6 | c.1522C>A p.L508M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV100842962; called by muse, mutect2, varscan2
- SLC6A2 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV54922722, COSV99574790; called by muse, mutect2, varscan2
- SLC6A4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as COSV99911641; called by muse, mutect2, varscan2
- SLC6A6 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); catalogued as COSV100692565; called by muse, mutect2, varscan2
- SLITRK1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1274976383, COSV65677898; called by muse, mutect2, varscan2
- SLITRK6 | c.2358G>T p.M786I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101233312; called by muse, mutect2, varscan2
- SMR3A | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV99895887; called by muse, mutect2, varscan2
- SORCS1 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99551142; called by muse, mutect2, varscan2
- SORCS3 | c.695+1G>A p.X232_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100865721; called by muse, mutect2, varscan2
- SOX14 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs917072602, COSV100048372; called by muse, mutect2, varscan2
- SPAG16 | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.572); catalogued as COSV100536532; called by muse, mutect2, varscan2
- SPAG17 | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.479); catalogued as COSV100310936; called by muse, mutect2, varscan2
- SPANXN2 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); catalogued as COSV65129952; called by muse, mutect2, varscan2
- SPATA31E1 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100351223; called by muse, mutect2, varscan2
- SPEG | c.5000G>T p.R1667L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100405884, COSV56676094; called by muse, mutect2, varscan2
- SRC | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100658272, COSV62440445; called by muse, mutect2, varscan2
- SSH3 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149465975; called by mutect2, varscan2
- SSTR1 | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 73/223 reads (33%) | catalogued as COSV99943216; called by muse, mutect2, varscan2
- SSX7 | c.81T>A p.D27E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99994060; called by muse, mutect2, varscan2
- ST14 | c.879G>T p.L293F | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV99599226; called by muse, mutect2, varscan2
- STAM | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101092411; called by muse, mutect2, varscan2
- STON2 | c.1289G>A p.S430N (on ENST00000649389 / NM_001366849.2; = p.S373N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99964687, COSV99965283; called by muse, mutect2, varscan2
- STYXL1 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1554566971, COSV99951695; called by muse, mutect2, varscan2
- SYCP2L | c.2183C>A p.P728Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99305970; called by muse, mutect2, varscan2
- TACR2 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100964836; called by muse, mutect2, varscan2
- TAS2R1 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV66778858, COSV66779746; called by muse, mutect2, varscan2
- TBX10 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316311987, COSV100039971; called by muse, mutect2, varscan2
- TBX22 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100960979, COSV64786362; called by muse, mutect2, varscan2
- TBX4 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99540795; called by muse, mutect2, varscan2
- TECRL | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101169508; called by muse, mutect2, varscan2
- TEKT4 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782653928, COSV99726813; called by muse, mutect2
- TENM3 | c.4658T>A p.I1553N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV101305548; called by muse, mutect2, varscan2
- TFDP1 | c.387G>C p.R129S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV100946062; called by muse, mutect2, varscan2
- TG | c.1526T>C p.F509S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV99603825; called by muse, mutect2, varscan2
- TGM2 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100821808; called by muse, mutect2, varscan2
- TGM6 | c.7+1G>T p.X3_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as rs772567551, COSV99172946; called by muse, mutect2, varscan2
- THBS2 | c.1276A>T p.S426C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV100828144; called by muse, mutect2, varscan2
- TIAM1 | c.404A>C p.Y135S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.138); catalogued as COSV99739668; called by muse, mutect2, varscan2
- TLNRD1 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV99146278; called by muse, mutect2, varscan2
- TMEM138 | c.158T>G p.I53S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99582762; called by muse, mutect2, varscan2
- TMEM174 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV99703852; called by muse, mutect2, varscan2
- TMOD1 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99404267; called by muse, mutect2, varscan2
- TMPRSS15 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99519599; called by muse, mutect2, varscan2
- TNR | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as rs749572126, COSV99692087; called by muse, mutect2, varscan2
- TNRC6A | c.3778G>T p.G1260C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs766819589, COSV100170617; called by mutect2, varscan2
- TNRC6A | c.5232G>T p.L1744F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100170620; called by muse, mutect2, varscan2
- TOGARAM1 | c.3958G>C p.V1320L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100818306; called by muse, mutect2
- TOGARAM2 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as rs1017129692, COSV65422402; called by muse, mutect2, varscan2
- TPO | c.2435C>A p.A812E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100222217, COSV100222438; called by muse, mutect2, varscan2
- TRDMT1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as COSV100004199; called by muse, mutect2, varscan2
- TRIM43 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as COSV55529456, COSV99720187; called by mutect2, varscan2
- TRIM51 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99793279; called by muse, mutect2, varscan2
- TRPA1 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763688385, COSV100085485; called by mutect2, varscan2
- TSHR | c.2024C>A p.P675Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53317558, COSV99993064; called by muse, mutect2, varscan2
- TSHZ1 | c.340G>T p.A114S (on ENST00000580243 / NM_001308210.2; = p.A69S on NM_005786.6) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100433974; called by muse, mutect2, varscan2
- TTC17 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.278); catalogued as rs758372001, COSV99236285; called by muse, mutect2, varscan2
- TTC21B | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99693053; called by muse, mutect2
- TTN | c.62827T>A p.W20943R (on ENST00000591111; = p.W13519R on NM_003319.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV100634613; called by muse, mutect2, varscan2
- TUBB4B | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (1); catalogued as COSV100458276; called by muse, mutect2, varscan2
- TXNDC16 | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99909765; called by muse, mutect2, varscan2
- UBD | c.134T>G p.V45G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV100590180; called by muse, mutect2, varscan2
- UGT2B11 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101485312; called by muse, mutect2, varscan2
- UNC80 | c.455T>A p.V152D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV99781407; called by muse, mutect2, varscan2
- UQCRH | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs762474674, COSV61177417; called by muse, mutect2, varscan2
- URGCP | c.133G>T p.E45* (on ENST00000453200 / NM_001077663.3; = p.E36* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 93/152 reads (61%) | catalogued as COSV99788055; called by muse, mutect2, varscan2
- USH2A | c.14225C>G p.T4742R | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370157230, COSV56402400; called by muse, mutect2
- USH2A | c.3547A>G p.I1183V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV56349605; called by muse, mutect2
- UXS1 | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99308923; called by muse, mutect2
- VAV2 | c.1217C>G p.P406R (on ENST00000371850 / NM_001134398.2; = p.P401R on NM_003371.4) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100896346; called by muse, mutect2, varscan2
- VGLL1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65702879, COSV65702983; called by muse, mutect2, varscan2
- VPS35 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100140862; called by muse, mutect2, varscan2
- VPS41 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV59654911; called by muse, mutect2, varscan2
- VWA7 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 109/188 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100791868; called by muse, mutect2, varscan2
- WDR53 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100218163; called by muse, mutect2, varscan2
- WDR64 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 40/72 reads (56%) | catalogued as COSV100844130; called by muse, mutect2
- WFIKKN2 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.201); catalogued as COSV100260165; called by muse, mutect2, varscan2
- WNT3A | c.490A>G p.M164V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV99470283; called by muse, mutect2, varscan2
- WNT7A | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99541866; called by muse, mutect2, varscan2
- XBP1 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV53275137; called by muse, mutect2, varscan2
- XCR1 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs905380713, COSV100499504, COSV58570484; called by muse, mutect2, varscan2
- XIRP2 | c.4034C>A p.S1345Y (on ENST00000628543; = p.S1520Y on NM_152381.6) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99748730; called by muse, varscan2
- ZBTB24 | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100018791; called by muse, mutect2, varscan2
- ZBTB25 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV101170765; called by muse, mutect2, varscan2
- ZEB1 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD072518, COSV100315269; called by muse, mutect2, varscan2
- ZFHX3 | c.8641A>G p.M2881V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99215247; called by muse, mutect2, varscan2
- ZFHX4 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV99268882; called by muse, mutect2, varscan2
- ZFPL1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750879428, COSV99298081; called by muse, mutect2, varscan2
- ZFYVE26 | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100720736; called by muse, mutect2, varscan2
- ZIC1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51555532, COSV99292574; called by muse, mutect2, varscan2
- ZIC5 | c.1962del p.N655Tfs*14 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as COSV57438646; called by mutect2, pindel, varscan2
- ZIM3 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99518845; called by muse, mutect2, varscan2
- ZMYM2 | c.3959A>T p.Q1320L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101244181; called by muse, mutect2, varscan2
- ZNF135 | c.1327T>A p.C443S (on ENST00000313434 / NM_001289401.2; = p.C455S on NM_003436.4) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57884018; called by muse, mutect2
- ZNF341 | c.1474G>T p.E492* (on ENST00000375200 / NM_001282935.1; = p.E485* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100678167; called by muse, mutect2, varscan2
- ZNF423 | c.88G>T p.V30L (on ENST00000563137 / NM_001379286.1; = p.V22L on NM_015069.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV99284228; called by muse, mutect2, varscan2
- ZNF529 | c.1414C>G p.H472D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485443; called by muse, mutect2, varscan2
- ZNF536 | c.837C>A p.C279* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100836144; called by muse, mutect2
- ZNF607 | c.1968del p.S656Rfs*68 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as COSV100777988; called by mutect2, pindel, varscan2
- ZNF615 | c.1858G>T p.G620* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100944029; called by muse, mutect2, varscan2
- ZNF638 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as rs774616770, COSV100040272; called by muse, mutect2, varscan2
- ZNF648 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100374860; called by muse, mutect2, varscan2
- ZNF675 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV100704954; called by muse, mutect2, varscan2
- ZNF695 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1432893129, COSV60585663; called by muse, mutect2
- ZNF695 | c.1072G>T p.G358* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100377805; called by muse, mutect2
- ZNF804A | c.3406C>A p.P1136T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100168885, COSV100170672; called by muse, mutect2, varscan2
- ZNF804B | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100306857, COSV60823983; called by muse, mutect2, varscan2
- ZNF835 | c.1513C>A p.P505T | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV101606417; called by muse, mutect2, varscan2
- ZPLD1 | c.170C>A p.T57K (on ENST00000466937 / NM_001329788.1; = p.T73K on NM_175056.2) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100083641; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2805C>A p.H935Q | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.3068G>T p.G1023V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- ARHGEF15 | c.2157del p.T720Pfs*75 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by pindel, varscan2
- ASCL3 | c.32del p.P11Lfs*15 | Frame Shift Del (DEL) | VAF 42/170 reads (25%) | called by mutect2, pindel, varscan2
- COL27A1 | c.33del p.T12Qfs*18 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- DDX3X | c.1261_1264del p.V421Kfs*13 (on ENST00000399959; = p.V422Kfs*13 on NM_001356.5) | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- DNM1P46 | n.135C>T | Splice Region (SNP) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- DOCK9 | c.1598del p.K533Rfs*47 (on ENST00000376460 / NM_001366676.2; = p.K534Rfs*47 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- EPB42 | c.700del p.Q234Rfs*9 (on ENST00000441366 / NM_001114134.2; = p.Q264Rfs*9 on NM_000119.3) | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel*, varscan2
- FOXD4L6 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); called by mutect2, varscan2
- GDF10 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR179 | c.4990C>T p.P1664S (on ENST00000621958; = p.P1663S on NM_001004334.4) | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- HS3ST2 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.055); called by muse, mutect2
- IGHV3OR16-8 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- IRAK2 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRX4 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- JADE1 | c.215dup p.L72Ffs*32 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- LONP2 | c.1441_1447del p.D481Lfs*6 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | called by mutect2, pindel, varscan2
- MEMO1 | c.824dup p.S276Vfs*5 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- NFASC | c.660_661delinsT p.H221Tfs*111 (on ENST00000339876 / NM_001378329.1; = p.H215Tfs*24 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | called by pindel, varscan2*
- OR10G8 | c.597del p.F199Lfs*2 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- OR2C3 | c.427del p.L145* | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- OR4Q3 | c.341A>T p.H114L | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POF1B | c.946T>A p.Y316N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP4R2 | c.739del p.R247Dfs*27 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, varscan2
- PTPN4 | c.2151del p.S718Afs*3 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel
- RAB13 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by mutect2, varscan2
- RAB13 | c.555del p.S186Vfs*4 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- RAB6D | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SSUH2 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.053); called by muse, mutect2
- TRAV18 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAV21 | c.47G>T p.W16L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM75P | c.1113del p.T372Qfs*35 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- VPS13B | c.6625_6627del p.C2209del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- WASHC2A | c.3252A>T p.R1084S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- XIRP2 | c.6760del p.L2254Ffs*5 (on ENST00000628543; = p.L2429Ffs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- AANAT | c.606C>A p.R202= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99166290; called by muse, mutect2, varscan2
- ACKR1 | c.36C>G p.P12= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs372629822; called by muse, mutect2, varscan2
- ACTR8 | c.756A>T p.I252= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99213929; called by muse, mutect2
- ADGRG4 | c.483G>A p.G161= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs746776907, COSV99797360; called by muse, mutect2, varscan2
- AGAP6 | c.1692G>T p.L564= (on ENST00000374056 / NM_001365867.1; = p.L587= on NM_001077665.2) | Silent (SNP) | VAF 15/89 reads (17%) | called by mutect2, varscan2
- AHNAK2 | c.13824G>T p.A4608= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV100319232, COSV60913258; called by muse, mutect2, varscan2
- AHNAK2 | c.4863G>C p.L1621= | Silent (SNP) | VAF 33/274 reads (12%) | catalogued as rs376710681, COSV100319233; called by muse, mutect2, varscan2
- AL645922.1 | c.297G>T p.V99= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as COSV100191589; called by muse, mutect2, varscan2
- ALOX15 | c.1284G>C p.L428= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV99541817; called by muse, mutect2, varscan2
- ANGPTL5 | c.1050T>C p.S350= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV100528050; called by muse, mutect2, varscan2
- ANK2 | c.8322C>T p.G2774= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs757490110, COSV52193044; called by muse, mutect2, varscan2
- AP3S2 | c.513A>T p.P171= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100318688, COSV60518037; called by muse, mutect2, varscan2
- APOB | c.6072T>A p.I2024= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99268632; called by muse, mutect2, varscan2
- APP | c.2037A>T p.S679= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV60999116; called by muse, mutect2, varscan2
- ATP11C | c.2772G>T p.L924= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV100558839; called by muse, mutect2, varscan2
- ATP1A2 | c.2451C>T p.I817= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100768217; called by muse, mutect2, varscan2
- ATP1B4 | c.838C>A p.R280= (on ENST00000218008 / NM_001142447.3; = p.R276= on NM_012069.5) | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV99486624; called by muse, mutect2, varscan2
- ATP2B2 | c.1191G>T p.T397= (on ENST00000352432; = p.T363= on NM_001683.5) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100659632; called by muse, mutect2, varscan2
- AURKB | c.723C>T p.P241= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV100298936; called by muse, mutect2, varscan2
- BCL11A | c.585G>T p.G195= (on ENST00000335712 / NM_001365609.1; = p.G229= on NM_018014.4) | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100186728; called by muse, mutect2, varscan2
- BSN | c.7668G>T p.R2556= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99610117; called by muse, mutect2, varscan2
- CACNA1G | c.5871G>T p.G1957= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100662721; called by muse, mutect2, varscan2
- CADM2 | c.1248C>A p.A416= (on ENST00000407528 / NM_001167674.2; = p.A418= on NM_153184.4) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV67372097; called by muse, mutect2, varscan2
- CASP5 | c.1186C>T p.L396= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99508195; called by muse, mutect2, varscan2
- CD163 | c.1842A>T p.I614= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100776188; called by muse, mutect2, varscan2
- CD177 | c.1185G>A p.K395= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100946105; called by muse, mutect2, varscan2
- CDC25C | c.840G>T p.G280= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100087000; called by muse, mutect2, varscan2
- CDH9 | c.1554C>A p.P518= | Silent (SNP) | VAF 21/205 reads (10%) | catalogued as COSV50252345, COSV50362557; called by muse, mutect2
- CDKN2A | c.444G>A p.A148= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs768280139, COSV100446616; called by muse, mutect2, varscan2
- CELA3B | c.708C>A p.T236= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100448770, COSV100448896; called by muse, mutect2, varscan2
- CILP | c.1473C>T p.I491= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1202246011, COSV99974059; called by muse, mutect2, varscan2
- CMA1 | c.678C>A p.P226= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99157837; called by muse, mutect2, varscan2
- CNTN2 | c.1209C>A p.T403= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100085603; called by muse, mutect2, varscan2
- COL6A6 | c.3321G>A p.L1107= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100651083; called by muse, mutect2, varscan2
- CRB1 | c.3363G>A p.Q1121= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100957588, COSV66329656; called by muse, mutect2, varscan2
- CRIP2 | c.555C>A p.P185= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs782481300, COSV100231790; called by muse, mutect2, varscan2
- CSF2RA | c.693G>C p.T231= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100818007; called by muse, mutect2
- CTAGE1 | c.1914T>C p.N638= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV101194723; called by muse, mutect2, varscan2
- CUX2 | c.2448T>C p.S816= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99921025; called by muse, mutect2, varscan2
- DBH | c.1800G>A p.Q600= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV101257255; called by muse, mutect2, varscan2
- DCDC1 | c.4776T>C p.C1592= (on ENST00000597505 / NM_001367979.1; = p.C699= on NM_020869.3) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100360218; called by muse, mutect2
- DDX39B | c.1266C>G p.S422= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100871103; called by muse, mutect2, varscan2
- DEFB118 | c.45C>A p.P15= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV53621091; called by muse, mutect2, varscan2
- DNAH3 | c.5886C>G p.T1962= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54502330, COSV99771263; called by muse, mutect2, varscan2
- DNAH8 | c.9771T>C p.F3257= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100547435; called by muse, mutect2
- DPP10 | c.843G>T p.P281= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs146251151, COSV100071178; called by muse, varscan2
- DPYS | c.1158T>C p.F386= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs367990408, COSV59827144; called by muse, mutect2
- ECT2 | c.837G>T p.L279= (on ENST00000392692 / NM_001349098.2; = p.L248= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99222048; called by muse, mutect2, varscan2
- ELAVL4 | c.534C>A p.I178= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV100836963, COSV100836964; called by muse, mutect2, varscan2
- EPHA5 | c.1212G>A p.V404= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99901892; called by muse, mutect2, varscan2
- ERICH6 | c.1263C>A p.V421= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99902117; called by muse, mutect2, varscan2
- FAT3 | c.1602G>A p.L534= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53096893; called by muse, mutect2, varscan2
- FCGR1A | c.750T>C p.A250= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100977320; called by muse, mutect2, varscan2
- FGF12 | c.276C>A p.T92= (on ENST00000454309 / NM_021032.5; = p.T30= on NM_004113.6) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV53157654, COSV99284389; called by muse, mutect2, varscan2
- FGF5 | c.573C>T p.A191= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100428114; called by muse, mutect2, varscan2
- FREM1 | c.180G>T p.V60= | Silent (SNP) | VAF 2/20 reads (10%) | called by muse, mutect2
- GOLM1 | c.174A>T p.A58= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99974531; called by muse, mutect2, varscan2
- GRIK1 | c.492G>C p.L164= | Silent (SNP) | VAF 45/171 reads (26%) | catalogued as COSV100518198; called by muse, mutect2, varscan2
- HEATR5A | c.3505C>T p.L1169= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1566755003, COSV101120701; called by muse, mutect2, varscan2
- HMCN1 | c.6252G>T p.V2084= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV99637426; called by muse, mutect2
- IGF2BP1 | c.462C>A p.I154= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99289222; called by muse, mutect2, varscan2
- IGHV4-28 | c.180C>T p.P60= | Silent (SNP) | VAF 34/216 reads (16%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.345T>C p.S115= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- IL4I1 | c.624G>A p.R208= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV99680990; called by muse, mutect2, varscan2
- INSC | c.726G>T p.L242= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV101089267, COSV101089785; called by muse, mutect2, varscan2
- INSRR | c.3171C>G p.V1057= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100948225; called by muse, mutect2, varscan2
- INSRR | c.2778C>T p.A926= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100948226; called by muse, mutect2, varscan2
- ITIH5 | c.2166A>G p.G722= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99906120; called by muse, varscan2
- ITSN1 | c.2718G>T p.V906= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101180641; called by muse, mutect2, varscan2
- KCNH5 | c.2289G>T p.T763= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100528476, COSV59780498; called by muse, mutect2, varscan2
- KCNJ4 | c.987C>T p.Y329= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100341572; called by muse, mutect2, varscan2
- KCNJ8 | c.918C>G p.T306= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99557759; called by muse, mutect2, varscan2
- KIF27 | c.2319C>G p.V773= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs765634941, COSV99927363; called by mutect2, varscan2
- KIF2B | c.1806C>A p.P602= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV52127972; called by muse, mutect2, varscan2
- KIFC2 | c.1362A>G p.P454= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV100024035; called by muse, mutect2, varscan2
- LCE3E | c.195C>A p.R65= | Silent (SNP) | VAF 19/200 reads (10%) | catalogued as COSV64231565; called by muse, mutect2, varscan2
- LRRC17 | c.105G>T p.A35= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs377630961, COSV50864318, COSV99978758; called by muse, mutect2, varscan2
- LRRC32 | c.1194G>C p.L398= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99477404; called by muse, mutect2, varscan2
- LRRC7 | c.3150T>C p.S1050= (on ENST00000651989 / NM_001370785.2; = p.S1017= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99230477; called by mutect2, varscan2
- MAML1 | c.648G>T p.L216= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV99483520; called by muse, mutect2, varscan2
- MAOB | c.1474C>T p.L492= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100956277; called by mutect2, varscan2
- MAP7D2 | c.216G>T p.R72= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101107645; called by muse, mutect2
- MARK1 | c.180C>T p.Y60= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100857605; called by muse, mutect2, varscan2
- MUC15 | c.519A>C p.S173= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs894898924, COSV99846730; called by muse, mutect2, varscan2
- MUC16 | c.26064C>A p.S8688= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101202110; called by muse, mutect2, varscan2
- MYLK | c.3423C>T p.T1141= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100659794; called by muse, mutect2, varscan2
- MYO18B | c.1194C>A p.P398= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100125549; called by muse, mutect2
- N4BP3 | c.315G>T p.R105= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV99200854; called by muse, mutect2, varscan2
- NIPAL4 | c.348T>C p.Y116= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs759747425, COSV100357356; called by mutect2, varscan2
- NOD2 | c.1605G>T p.L535= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV56054360; called by muse, mutect2, varscan2
- NPFFR1 | c.306G>T p.V102= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99525052; called by muse, mutect2, varscan2
- NUP107 | c.792A>T p.R264= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99972144; called by muse, mutect2, varscan2
- OLFM4 | c.9C>A p.P3= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV99524637; called by muse, mutect2
- OR13C2 | c.21C>T p.T7= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs781584720, COSV73377700, COSV73377717; called by muse, mutect2, varscan2
- OR14A16 | c.819G>T p.V273= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100713890; called by muse, mutect2
- OR4N5 | c.435G>C p.S145= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as COSV100374267; called by muse, mutect2, varscan2
- OR5P3 | c.285T>C p.A95= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs369132487; called by muse, mutect2, varscan2
- OR7A10 | c.57G>A p.E19= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV50166451; called by muse, varscan2
- OTUD6A | c.498T>A p.S166= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100611109; called by muse, mutect2
- PARD3B | c.2937A>G p.P979= (on ENST00000406610 / NM_001302769.2; = p.P910= on NM_057177.7) | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100595667; called by muse, varscan2
- PCDH8 | c.1770C>A p.S590= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100132124; called by muse, mutect2
- PCDHA7 | c.2130G>T p.L710= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100971111; called by muse, mutect2, varscan2
- PCDHB13 | c.2319C>T p.N773= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99507988; called by muse, mutect2, varscan2
- PCDHB7 | c.687C>T p.R229= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99177566; called by muse, mutect2, varscan2
- PCSK4 | c.801G>T p.T267= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs754788014, COSV99278915; called by muse, mutect2, varscan2
- PHKG1 | c.954C>T p.I318= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99305489; called by muse, mutect2, varscan2
- PIK3AP1 | c.2121G>C p.T707= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV100226317; called by muse, mutect2, varscan2
- PKN1 | c.1605G>T p.G535= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99661952; called by muse, mutect2, varscan2
- PLXNA4 | c.957G>T p.G319= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs758798267, COSV100327873; called by muse, mutect2, varscan2
- PNLIPRP3 | c.672C>A p.I224= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100982657; called by muse, mutect2, varscan2
- PODNL1 | c.1296C>T p.N432= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99583111; called by muse, mutect2, varscan2
- PSMB11 | c.685C>A p.R229= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99944366; called by muse, mutect2, varscan2
- RBM41 | c.237C>T p.D79= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99179850; called by muse, mutect2, varscan2
- RGS7BP | c.234G>T p.S78= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100471139; called by muse, mutect2
- RHOH | c.48G>C p.G16= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs575059532, COSV101110547, COSV101110638; called by muse, mutect2, varscan2
- RNASE8 | c.300C>T p.H100= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs77979750, COSV100373547; called by muse, mutect2, varscan2
- RTL4 | c.624G>C p.L208= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100466124, COSV100466191; called by muse, mutect2, varscan2
- RYR1 | c.1765C>T p.L589= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1262184618, COSV100617281; called by muse, mutect2, varscan2
- RYR2 | c.8649C>A p.A2883= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100773269, COSV63686359; called by muse, mutect2, varscan2
- SCNN1G | c.66G>C p.A22= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100264591, COSV55598236; called by muse, mutect2, varscan2
- SEMA3G | c.2214A>G p.S738= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV99203375; called by muse, mutect2, varscan2
- SEMA5A | c.2646G>T p.G882= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV101228258; called by muse, mutect2
- SIGLEC12 | c.73C>T p.L25= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs747862814, COSV99389667; called by mutect2, varscan2
- SLC10A4 | c.627C>A p.L209= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV99907037; called by muse, mutect2, varscan2
- SLC14A2 | c.939G>A p.S313= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs377498712; called by muse, mutect2
- SLC15A1 | c.2034C>A p.I678= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs181189989, COSV64729992; called by muse, mutect2, varscan2
- SLIT3 | c.3240C>A p.A1080= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100270633; called by muse, mutect2, varscan2
- SLITRK2 | c.1140C>G p.L380= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV100158325, COSV59429405; called by muse, mutect2, varscan2
- SNAPC4 | c.171G>T p.P57= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100047784, COSV53733957; called by muse, mutect2, varscan2
- SORCS2 | c.1080A>C p.S360= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV100214269; called by muse, mutect2, varscan2
- SOX14 | c.339G>T p.G113= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100048370; called by muse, mutect2, varscan2
- SYBU | c.597G>T p.P199= (on ENST00000276646 / NM_001099754.2; = p.P198= on NM_017786.6) | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as COSV99406764; called by muse, mutect2
- TBX15 | c.798G>T p.G266= (on ENST00000369429 / NM_001330677.2; = p.G160= on NM_152380.3) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99254298, COSV99254932; called by muse, mutect2, varscan2
- TBXA2R | c.39G>T p.R13= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1033857372, COSV100916346; called by muse, mutect2, varscan2
- TEP1 | c.60G>T p.R20= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99403518; called by muse, mutect2, varscan2
- THAP9 | c.546A>G p.E182= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100156020; called by muse, mutect2, varscan2
- TLE6 | c.1077G>T p.V359= (on ENST00000246112 / NM_001143986.2; = p.V236= on NM_024760.3) | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99858650; called by muse, mutect2
- TMEM39B | c.549C>T p.F183= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100298325; called by muse, mutect2, varscan2
- TMPRSS9 | c.1026C>A p.I342= (on ENST00000648592; = p.I308= on NM_182973.2) | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV100211823; called by muse, mutect2, varscan2
- TRAV20 | c.192C>A p.G64= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TSPEAR | c.1035C>G p.A345= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100555873; called by muse, mutect2, varscan2
- TTC21A | c.1437C>A p.I479= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100087778, COSV57184901; called by muse, mutect2, varscan2
- VAC14 | c.2094C>T p.Y698= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs368686568, COSV99935210; called by muse, mutect2, varscan2
- VASH1 | c.645C>T p.Y215= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs768715503, COSV99388263; called by muse, mutect2, varscan2
- ZBTB26 | c.1126C>T p.L376= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101021175; called by muse, mutect2, varscan2
- ZFHX4 | c.7020T>C p.D2340= | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as COSV99268884; called by muse, mutect2, varscan2
- ZNF479 | c.267G>C p.T89= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100482521, COSV100483164, COSV58639204; called by muse, mutect2, varscan2
- ZNF577 | c.435C>G p.L145= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100031369; called by muse, mutect2, varscan2
- ZNF648 | c.147T>C p.A49= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV100374862; called by muse, mutect2, varscan2
- C5orf64 | n.513-44615G>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- DIRC1 | n.569del | RNA (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel*, varscan2
- EPB41L3 | chr18:5630433 G>A | 5'Flank (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8136C>A | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34905G>T | Intron (SNP) | VAF 56/103 reads (54%) | catalogued as COSV99399623; called by muse, mutect2, varscan2
- H2BP2 | n.1062-377G>T | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- KRT18P55 | n.848A>T | RNA (SNP) | VAF 60/105 reads (57%) | called by muse, mutect2, varscan2
- LLCFC1 | c.158-34A>G | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100787346; called by muse, mutect2, varscan2
- MIR520G | n.47G>C | RNA (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- MORF4 | n.810G>A | RNA (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- MORF4 | n.424C>A | RNA (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- PAX7 | c.1402+29del | Intron (DEL) | VAF 7/69 reads (10%) | catalogued as rs1557560511; called by mutect2, pindel
- PDE9A | c.219-1491G>T | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99372399; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1195G>C | RNA (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- RPS12 | c.337-208A>G | Intron (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100016415; called by muse, mutect2, varscan2
- SMOX | c.1531-475C>G | Intron (SNP) | VAF 43/78 reads (55%) | catalogued as COSV99603707; called by muse, mutect2, varscan2
- SNORD115-21 | n.30G>C | RNA (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-9 | n.67T>C | RNA (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- TBX5 | c.982+42C>A | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100091188; called by muse, mutect2, varscan2
- TBX5 | c.982+41C>A | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100092419; called by muse, mutect2, varscan2
- TPK1 | c.185+15148C>T | Intron (SNP) | VAF 22/50 reads (44%) | catalogued as rs767402148, COSV100766146; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439535 CG>T | 3'Flank (DEL) | VAF 14/128 reads (11%) | called by pindel, varscan2*
- VPS26C | chr21:37221444 A>G | 3'Flank (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- XIRP2 | c.*78G>C | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99748733; called by muse, mutect2, varscan2
- ZNF131 | c.*2A>G | 3'UTR (SNP) | VAF 7/44 reads (16%) | catalogued as rs760735508, COSV100185793; called by muse, mutect2, varscan2
